CPTAC case C3L-00589 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a40e29b-aaa0-4de4-949e-e4a5d6295bed

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1936; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 80.3 years (29,322 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,752 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,752 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 4 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 25; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 350 days; Disease response: Complete Response.
- Days to follow up: 613 days (1.7 years); Disease response: Complete Response.
- Days to follow up: 1,047 days (2.9 years); Disease response: Complete Response.
- Days to follow up: 1,397 days (3.8 years); Disease response: Complete Response.
- Days to follow up: 1,752 days (4.8 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 84 kg; Height: 175 cm; BMI: 27.43; Comorbidities: Hypertension.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 12; Cigarettes per day: 20; Tobacco smoking onset year: 1956; Tobacco smoking quit year: 1968; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 12.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00589-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 145 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00589-21: Section location: Head; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-00589-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 138 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00589-22: Section location: Head; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-00589-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 173 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00589-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
